CCDI case PBCPRD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/64940bd6-a776-4aca-bd28-7c7213a90557

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Atypical meningioma: ICD-O-3 morphology code: 9539/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,290 days).

Biospecimens (3 samples)
- Sample 0DWWMG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWWMN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWWN5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
